Gene-level copy-number profile of tumor specimen TCGA-WE-A8ZY-06A from TCGA case TCGA-WE-A8ZY, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 65.3 years (23,843 days).
Specimen TCGA-WE-A8ZY-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.3ec11ecb-44df-4759-91c6-3040f39f1767.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-WE-A8ZY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/36687392-832e-4bf2-a04e-520c0f78a82a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,699; copy number 2: 24,447; copy number 3: 16,390; copy number 4: 13,943; copy number 5: 85; copy number 6: 3,186; copy number 17: 18; copy number 18: 34; copy number 38: 12; copy number 45: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-WE-A8ZY-06A-11D-A371-01): tumor purity 0.81, ploidy 2.86, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,340 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:75,046,463–75,199,520, 1 gene, copy number 5 (within-gene range 4–5): TACR1.
- chr2:75,154,366–83,657,842, 84 genes, copy number 5 (broad region; genes not listed).
- chr3:11,745–198,222,513, 3,185 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr11:59,706,057–60,608,418, 34 genes, copy number 18 (within-gene range 2–18): RN7SKP192, OR10V1, STX3, OR10Y1P, OR10V3P, OR10V2P, AP000640.1, FABP5P7, MRPL16, CBLIF, TCN1, OOSP3, SRD5A3P1, OOSP1, AP000790.1, OOSP4A, OOSP4B, OOSP2, MS4A3, AP000790.2, MS4A2, LINC02705, MS4A6A, MS4A4A, MS4A4E, MIR6503, MS4A6E, MS4A7, MS4A14, MS4A5, MS4A1, MS4A12, MS4A13, MS4A19P.
- chr12:37,575,587–39,539,851, 24 genes, copy number 6–45: ZNF970P, AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.4, AC121334.1, AC121334.2.
- chr12:68,746,125–69,274,358, 12 genes, copy number 38 (within-gene range 2–38): SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6.

Autosomal genes at a single copy (total copy number 1): 1,699. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
